Somatic mutation profile of tumor specimen TCGA-FY-A40M-01A (aliquot TCGA-FY-A40M-01A-11D-A23M-08) from TCGA case TCGA-FY-A40M, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 51.3 years (18,722 days).
Specimen TCGA-FY-A40M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 050fc801-a5f2-4dca-a562-a34da0409182.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A40M-10A (Blood Derived Normal), aliquot TCGA-FY-A40M-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d06338f9-8828-4f05-a3e5-eede1a74c43a

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- CACNA1B | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs762168298, COSV53148885; called by muse, mutect2, varscan2
- COL8A1 | c.2035T>A p.F679I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as rs1047151837, COSV99657603; called by muse, mutect2, varscan2
- DVL3 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100493609; called by muse, varscan2
- GALNTL5 | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.389); catalogued as COSV101217772; called by muse, mutect2, varscan2
- KIT | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs139694927; ClinVar: uncertain significance; called by muse, mutect2
- LTBP1 | c.4145A>T p.D1382V (on ENST00000404816 / NM_206943.4; = p.D1056V on NM_000627.4) | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698136; called by muse, mutect2, varscan2
- SLITRK4 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.048); catalogued as rs782356458, COSV62022372; called by muse, varscan2
- KATNA1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2
- ANKH | c.207C>T p.F69= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV99414894; called by muse, mutect2, varscan2
- SLC22A23 | c.1563C>T p.S521= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100978204; called by muse, mutect2, varscan2
- SMARCA4 | c.63C>T p.G21= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100758435; called by muse, mutect2, varscan2
- USH1C | c.1155C>T p.L385= | Silent (SNP) | VAF 217/505 reads (43%) | catalogued as COSV99139806; called by muse, mutect2, varscan2
- ZNF385D | c.1044A>T p.A348= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99874360; called by muse, mutect2, varscan2
